Somatic mutation profile of tumor specimen 4f6b74fb-8b2e-40e2-87a5-02817e (aliquot 4f6b74fb-8b2e-40e2-87a5-02817e_D6) from CPTAC case 06BR003, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.9 years (27,374 days).
Specimen 4f6b74fb-8b2e-40e2-87a5-02817e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 726cc10a-1784-4550-aaf1-dd0c1b908ec8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a51ad581-647d-4da3-8b7e-7641b8 (Blood Derived Normal), aliquot a51ad581-647d-4da3-8b7e-7641b8_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4a18d1-45a9-4bd5-adee-1683341f2a77

The open-access MAF lists 62 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Intron 4, RNA 3, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 239/1573 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774944406, COSV64183872, COSV64184659; called by muse, mutect2, varscan2
- ASTN2 | c.2212G>A p.V738M (on ENST00000313400 / NM_001365069.1; = p.V687M on NM_014010.5) | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1368876596; called by muse, mutect2, varscan2
- ATP7B | c.4088C>A p.S1363Y | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM992829; called by muse, mutect2, varscan2
- CBX5 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV52938770; called by muse, mutect2, varscan2
- CBY2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs149478922; called by muse, mutect2, varscan2
- DUS3L | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs1241615862; called by muse, mutect2, varscan2
- EDEM3 | c.2358del p.V787Cfs*54 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV58927224; called by mutect2, pindel*, varscan2
- KCNA5 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 179/735 reads (24%) | catalogued as rs773432359, COSV52905456; called by muse, mutect2, varscan2
- MIR9-1HG | n.223C>T | Splice Region (SNP) | VAF 8/79 reads (10%) | catalogued as COSV59483244; called by muse, mutect2
- MUC16 | c.13619C>T p.T4540I | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as rs1200855227; called by muse, mutect2, varscan2
- NOS2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs377596177; called by muse, mutect2, varscan2
- OR5AN1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149354660; called by muse, mutect2, varscan2
- PARD6G | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs927673676, COSV62061010; called by muse, mutect2, varscan2
- PCDHGA11 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs749916401, COSV54031335; called by muse, mutect2, varscan2
- PCSK5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as rs745715735, COSV65083956; called by muse, mutect2, varscan2
- RYR2 | c.12851T>C p.F4284S | Missense Mutation (SNP) | VAF 68/461 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs781218991; called by muse, mutect2, varscan2
- SMYD4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769674542; called by muse, mutect2
- SOCS5 | c.1299G>C p.W433C | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1355896515; called by muse, mutect2
- TAS2R41 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs746160765, COSV68765768; called by muse, mutect2, varscan2
- ARRB1 | c.940A>T p.I314F | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- BRIP1 | c.3385T>A p.S1129T | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2
- CNTNAP5 | c.3398G>A p.R1133K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF1 | c.3348G>T p.Q1116H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC6 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELN | c.1537G>T p.V513F | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by mutect2, varscan2
- FMO4 | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- FNIP1 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- FRG2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.091); called by mutect2, varscan2
- GATA3 | c.1251dup p.T418Hfs*89 | Frame Shift Ins (INS) | VAF 132/247 reads (53%) | called by mutect2, pindel, varscan2
- KCNA5 | c.852C>A p.H284Q | Missense Mutation (SNP) | VAF 148/456 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOMO2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PHYH | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRAM1 | c.1757T>C p.I586T | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKX | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PRPF4B | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- R3HDM2 | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK6 | c.2494G>C p.D832H | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM40 | c.560C>T p.A187V (on ENST00000376724; = p.A158V on NM_138700.4) | Missense Mutation (SNP) | VAF 196/575 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TTN | c.18479A>G p.Q6160R (on ENST00000591111; = p.Q5233R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ZMYND8 | c.683A>G p.N228S (on ENST00000311275 / NM_001363741.2; = p.N248S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAMTS1 | c.1014G>A p.Q338= | Silent (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- ARRDC1 | c.597T>C p.P199= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as rs1199901251; called by muse, mutect2, varscan2
- ERICH3 | c.3159A>G p.E1053= | Silent (SNP) | VAF 50/180 reads (28%) | called by muse, mutect2, varscan2
- HMGB2 | c.351C>T p.H117= | Silent (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- LRRC58 | c.75C>G p.T25= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- NOS2 | c.906C>T p.F302= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs753280840, COSV58224082; called by muse, mutect2, varscan2
- PABPC5 | c.783A>G p.G261= | Silent (SNP) | VAF 55/210 reads (26%) | catalogued as rs757202588; called by muse, mutect2, varscan2
- PRR23B | c.345G>A p.Q115= | Silent (SNP) | VAF 98/457 reads (21%) | catalogued as COSV61493454; called by muse, mutect2, varscan2
- RAB10 | c.177G>A p.K59= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- RPL10L | c.267G>A p.V89= | Silent (SNP) | VAF 34/700 reads (5%) | called by muse, mutect2
- RSAD1 | c.999G>A p.V333= | Silent (SNP) | VAF 46/379 reads (12%) | catalogued as COSV51954605; called by muse, varscan2
- VPS13D | c.9663C>G p.S3221= | Silent (SNP) | VAF 37/130 reads (28%) | called by muse, mutect2, varscan2
- AGAP14P | n.24T>C | RNA (SNP) | VAF 218/641 reads (34%) | called by muse, mutect2, varscan2
- AL136982.4 | n.177_185del | RNA (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- CPT2 | c.-47A>G | 5'UTR (SNP) | VAF 22/84 reads (26%) | catalogued as rs1226895734; called by muse, mutect2, varscan2
- DDX17 | c.1447+1677C>T | Intron (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- DNM3 | c.1689+13301C>T | Intron (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- LIFR | c.257+39G>T | Intron (SNP) | VAF 85/184 reads (46%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92812G>A | Intron (SNP) | VAF 39/378 reads (10%) | called by muse, mutect2
- OR2L1P | n.653G>A | RNA (SNP) | VAF 97/597 reads (16%) | catalogued as rs759236876; called by muse, mutect2, varscan2
- RPL10 | c.-145G>A | 5'UTR (SNP) | VAF 160/638 reads (25%) | catalogued as COSV99186302; called by muse, mutect2, varscan2
- XIRP2 | c.*259T>G | 3'UTR (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
